Somatic mutation profile of tumor specimen TCGA-CN-4740-01A (aliquot TCGA-CN-4740-01A-01D-1434-08) from TCGA case TCGA-CN-4740, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 79.9 years (29,186 days).
Specimen TCGA-CN-4740-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2344458-0730-4947-a83d-2e8aeb7a9147.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-4740-10A (Blood Derived Normal), aliquot TCGA-CN-4740-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa775d65-e733-410c-a7e2-fe1e1eb209f4

The open-access MAF lists 136 somatic variants for this specimen: 108 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 26, Nonsense Mutation 5, Splice Site 2, 5'UTR 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C3 | c.110A>T p.K37M | Missense Mutation (SNP) | VAF 17/106 reads (16%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.357); catalogued as COSV63550964, COSV63551270; called by muse, mutect2, varscan2
- TP53 | c.97-1G>A p.X33_splice | Splice Site (SNP) | VAF 22/276 reads (8%) | hotspot (GDC flag); catalogued as CS971912, COSV52665806, COSV52762622, COSV52838014; called by muse, mutect2
- ABCA10 | c.4136+2T>A p.X1379_splice | Splice Site (SNP) | VAF 17/204 reads (8%) | catalogued as COSV99289164; called by muse, mutect2
- ADAMTS16 | c.1433A>G p.Y478C | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99942415; called by muse, mutect2
- ADORA1 | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV55142136, COSV99704669; called by muse, mutect2, varscan2
- AGBL5 | c.1469G>C p.R490T | Missense Mutation (SNP) | VAF 31/285 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100549362; called by muse, mutect2, varscan2
- AGMO | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 21/318 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV61105489, COSV61123901; called by muse, mutect2
- ALPK2 | c.3515C>T p.T1172M | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs140868694; called by mutect2, varscan2
- ALPK3 | c.1570G>T p.V524L | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.836); catalogued as COSV99361757; called by muse, mutect2, varscan2
- ANGPTL3 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.584); catalogued as CM090077, COSV99225601; called by muse, mutect2, varscan2
- ANKRD26 | c.3440G>A p.R1147Q | Missense Mutation (SNP) | VAF 36/376 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.314); catalogued as rs374176783; called by muse, mutect2
- ARID4A | c.2197G>C p.D733H | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.499); catalogued as COSV62161986; called by muse, mutect2
- ATP10B | c.478C>A p.Q160K | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs766480564, COSV58779956; called by muse, mutect2, varscan2
- ATP11C | c.830A>G p.Y277C | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100558407; called by muse, mutect2, varscan2
- ATP1A3 | c.2887G>A p.E963K (on ENST00000545399 / NM_001256214.2; = p.E950K on NM_152296.5) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as COSV100132478; called by muse, mutect2, varscan2
- BICC1 | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 17/234 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99570814; called by muse, mutect2
- C7 | c.2012T>G p.F671C | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV100496400; called by muse, mutect2
- CBLIF | c.900C>A p.S300R | Missense Mutation (SNP) | VAF 28/311 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV99951065; called by muse, mutect2
- CCDC88A | c.538G>C p.D180H | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV99711026; called by muse, mutect2
- CDADC1 | c.343C>A p.L115I | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.165); catalogued as COSV51913621, COSV99212597; called by muse, mutect2, varscan2
- CECR2 | c.1627G>C p.D543H (on ENST00000342247 / NM_001290047.2; = p.D360H on NM_001290046.1) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV99378834; called by muse, mutect2, varscan2
- CELSR1 | c.6181G>T p.A2061S | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.264); catalogued as COSV99419580; called by muse, mutect2, varscan2
- CEMIP2 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100987480; called by muse, mutect2, varscan2
- CEP350 | c.8719C>G p.Q2907E | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1184686924, COSV100855074; called by muse, mutect2
- COG7 | c.1232G>C p.R411T | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as COSV100207748; called by muse, mutect2
- COL14A1 | c.2281G>A p.D761N | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99920279; called by muse, mutect2
- COL23A1 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV101179556; called by muse, mutect2, varscan2
- CRYBG3 | c.6086C>T p.T2029M | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as rs371682309; called by muse, mutect2, varscan2
- CSPG5 | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.851); catalogued as rs1481617029, COSV99274097; called by muse, mutect2, varscan2
- CTSG | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.024); catalogued as COSV53536981; called by muse, mutect2, varscan2
- CXorf21 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1391027079, COSV100973344; called by muse, mutect2, varscan2
- DENND2D | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 10/144 reads (7%) | catalogued as rs1199105927, COSV62960187; called by muse, mutect2
- DNAH17 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV101103170; called by muse, mutect2, varscan2
- ECE1 | c.1669C>T p.Q557* | Nonsense Mutation (SNP) | VAF 10/73 reads (14%) | catalogued as COSV99942223; called by muse, mutect2, varscan2
- EFEMP1 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.203); catalogued as rs748310171, COSV62617100; ClinVar: likely benign; called by muse, mutect2
- ERLIN1 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as COSV100962306; called by muse, mutect2, varscan2
- ESYT3 | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV100004932; called by muse, mutect2, varscan2
- EXTL2 | c.631G>T p.V211L | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV100921123; called by muse, mutect2, varscan2
- FLRT2 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 89/409 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.238); catalogued as rs866102871, COSV58150691; called by muse, mutect2, varscan2
- FREM1 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as COSV101084927; called by muse, mutect2, varscan2
- GDA | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1052807844, COSV99429653; called by mutect2, varscan2
- GRIN2B | c.569T>C p.I190T | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.865); catalogued as COSV101663146; called by muse, mutect2, varscan2
- H2AC6 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100019863, COSV58417094; called by muse, mutect2, varscan2
- HEPACAM2 | c.823C>A p.H275N (on ENST00000394468 / NM_001039372.4; = p.H263N on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/458 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100506724; called by muse, mutect2
- HHIPL2 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs774553296, COSV100597035, COSV58565597; called by muse, mutect2
- HK1 | c.1541C>T p.S514F | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53860885; called by muse, mutect2
- IGF1R | c.3907G>A p.V1303I | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs45475702, COSV51417992; called by muse, varscan2
- IGLV2-23 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.446); catalogued as rs377577811; called by muse, mutect2
- KIAA1614 | c.200C>A p.P67H | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100851341; called by mutect2, varscan2
- LAMB4 | c.2272A>T p.M758L | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99225205; called by muse, mutect2, varscan2
- LIPI | c.802C>G p.Q268E | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100753937; called by muse, mutect2
- LRRC7 | c.2651C>T p.T884I (on ENST00000651989 / NM_001370785.2; = p.T851I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99228985; called by muse, mutect2
- LZTR1 | c.1292A>T p.E431V | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV99302198; called by muse, mutect2, varscan2
- MAPK15 | c.1000G>C p.E334Q | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.562); catalogued as COSV62027301; called by muse, mutect2
- MAPKBP1 | c.4252C>T p.Q1418* (on ENST00000456763 / NM_001128608.2; = p.Q1412* on NM_014994.3) | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as COSV99529994; called by muse, mutect2
- MCF2L2 | c.2563G>A p.D855N | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as rs1431019471, COSV100193603; called by muse, mutect2, varscan2
- MDN1 | c.12511G>A p.V4171I | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as rs373882628; called by muse, mutect2, varscan2
- MED1 | c.4705G>A p.E1569K | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.156); catalogued as COSV100328080; called by muse, mutect2, varscan2
- NAGA | c.1041G>A p.M347I | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV101124170; called by muse, mutect2, varscan2
- NME8 | c.900G>C p.M300I | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV99553717; called by muse, mutect2
- NRG2 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV99180811; called by muse, mutect2
- OR14I1 | c.88C>A p.L30M | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100700527; called by muse, mutect2
- OR5J2 | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 65/370 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV100399198; called by muse, mutect2, varscan2
- PARPBP | c.1094C>G p.A365G | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.725); catalogued as COSV100569281; called by muse, mutect2, varscan2
- PCDH18 | c.1055C>G p.P352R | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100787462; called by muse, mutect2, varscan2
- PCDHB6 | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 24/212 reads (11%) | catalogued as COSV50694999, COSV99170729; called by muse, mutect2, varscan2
- PCDHB6 | c.643G>C p.D215H | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99170733; called by muse, mutect2
- PCDHGA12 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 48/242 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52746765; called by muse, mutect2, varscan2
- PCDHGA12 | c.1880G>A p.R627H | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.431); catalogued as rs779250544, COSV99341819; called by muse, mutect2
- PGAP6 | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as COSV99170771; called by muse, mutect2, varscan2
- PPP2R2D | c.349C>G p.L117V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as COSV101409064, COSV70779699; called by muse, mutect2, varscan2
- PTPRT | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as rs868295248, COSV61972135, COSV62015052; called by muse, mutect2
- RAD54L | c.1059C>G p.F353L | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100914823; called by muse, mutect2
- RASSF9 | c.956A>C p.K319T | Missense Mutation (SNP) | VAF 44/428 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100771532; called by muse, mutect2
- RBL1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.771); catalogued as COSV100727250; called by muse, mutect2, varscan2
- RBM17 | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 13/149 reads (9%) | catalogued as COSV101159152; called by muse, mutect2
- RELN | c.6274G>A p.V2092M | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as rs752081680, COSV100633807; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPS5 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV52191906, COSV99545055; called by muse, mutect2, varscan2
- RPS6KA3 | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV101084605; called by muse, varscan2
- RYR3 | c.3589C>G p.Q1197E | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101213860; called by muse, mutect2, varscan2
- SBF1 | c.3440C>G p.S1147C | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV100817971, COSV62370536; called by muse, mutect2, varscan2
- SCLT1 | c.1582G>C p.E528Q | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV99828381; called by muse, mutect2
- SCN1A | c.3740C>T p.T1247M (on ENST00000303395 / NM_001202435.3; = p.T1236M on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs765403943, COSV57670644, COSV57671447; called by muse, mutect2, varscan2
- SCP2D1 | c.11G>C p.R4T | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99602166, COSV99602194; called by muse, mutect2, varscan2
- SEC23IP | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.033); catalogued as COSV100957044; called by muse, mutect2
- SHMT2 | c.564C>G p.I188M | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV100197325; called by muse, mutect2, varscan2
- SIGLEC1 | c.3896G>A p.R1299H | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.284); catalogued as rs374312370; called by muse, mutect2, varscan2
- SKA3 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.245); catalogued as rs766952195, COSV53435918; called by muse, mutect2, varscan2
- SMCHD1 | c.3143A>T p.K1048M | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99862314; called by muse, mutect2, varscan2
- SMG8 | c.2516G>A p.R839Q | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs199568785; called by muse, mutect2, varscan2
- SORBS2 | c.1718C>G p.S573C | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); catalogued as COSV99512263, COSV99512334; called by muse, mutect2, varscan2
- SORBS2 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 15/252 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV53010149; called by muse, mutect2
- SSH2 | c.3301G>C p.E1101Q | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.021); catalogued as COSV99282773; called by muse, mutect2
- SSTR2 | c.1038C>A p.D346E | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.028); catalogued as COSV100192182, COSV59535115; called by muse, mutect2, varscan2
- SWAP70 | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100014029; called by muse, mutect2
- TMTC2 | c.1691A>G p.Y564C | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100338673; called by muse, mutect2, varscan2
- TNPO2 | c.1435A>T p.M479L | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100790399; called by muse, mutect2, varscan2
- TP53I13 | c.152G>A p.R51K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.027); catalogued as rs1459649633, COSV99838019, COSV99838365; called by muse, mutect2
- TRRAP | c.10928G>A p.S3643N (on ENST00000359863 / NM_001244580.1; = p.S3614N on NM_003496.3) | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV100705479; called by muse, mutect2, varscan2
- TSR1 | c.904A>G p.I302V | Missense Mutation (SNP) | VAF 87/402 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.239); catalogued as COSV99280422; called by muse, mutect2, varscan2
- TTN | c.36629C>T p.T12210I (on ENST00000591111; = p.T4786I on NM_003319.4) | Missense Mutation (SNP) | VAF 19/219 reads (9%) | PolyPhen possibly damaging (0.776); catalogued as COSV100625156; called by muse, mutect2
- UBAP2L | c.1901C>T p.S634F | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV55178795, COSV99672011; called by muse, mutect2, varscan2
- UCP2 | c.48G>T p.K16N | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.495); catalogued as COSV100135150; called by muse, mutect2, varscan2
- VEPH1 | c.2018A>T p.D673V | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV100747903; called by muse, mutect2
- ZBTB45 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 74/725 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.04); catalogued as rs1405805250, COSV99564569; called by muse, mutect2, varscan2
- ZNF286A | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.066); catalogued as COSV101224697; called by muse, mutect2, varscan2
- AP1G1 | c.604T>C p.C202R | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SRPK2 | c.1456dup p.S486Ffs*3 | Frame Shift Ins (INS) | VAF 29/160 reads (18%) | called by mutect2, pindel, varscan2
- AGRN | c.4944G>C p.L1648= | Silent (SNP) | VAF 18/179 reads (10%) | catalogued as COSV101039016; called by muse, mutect2, varscan2
- ALPK2 | c.3835C>T p.L1279= | Silent (SNP) | VAF 32/289 reads (11%) | catalogued as COSV100864721; called by muse, mutect2, varscan2
- CD209 | c.807C>T p.F269= | Silent (SNP) | VAF 22/157 reads (14%) | catalogued as rs761378871, COSV52656677; called by muse, mutect2, varscan2
- CFAP206 | c.666C>T p.T222= | Silent (SNP) | VAF 12/110 reads (11%) | catalogued as rs1264738922, COSV99739943; called by muse, varscan2
- CRACD | c.3531G>A p.T1177= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as rs368466580, COSV99949836; called by muse, mutect2, varscan2
- CREBBP | c.2607C>G p.L869= | Silent (SNP) | VAF 16/124 reads (13%) | catalogued as rs375527347; called by muse, mutect2, varscan2
- DVL1 | c.528C>T p.D176= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV101127612, COSV66680208; called by muse, mutect2, varscan2
- ENAM | c.600T>C p.F200= | Silent (SNP) | VAF 76/418 reads (18%) | catalogued as COSV101253286; called by muse, mutect2, varscan2
- FECH | c.1104T>C p.A368= | Silent (SNP) | VAF 6/95 reads (6%) | catalogued as COSV100023750; called by muse, mutect2
- GLI1 | c.357C>T p.G119= | Silent (SNP) | VAF 26/169 reads (15%) | catalogued as rs746329155, COSV99954513; called by muse, mutect2, varscan2
- HYDIN | c.15075G>A p.K5025= | Silent (SNP) | VAF 8/146 reads (5%) | catalogued as COSV101125184; called by muse, mutect2
- KIFC3 | c.195C>G p.V65= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV101109328; called by muse, mutect2, varscan2
- KRI1 | c.1968G>A p.R656= | Silent (SNP) | VAF 22/282 reads (8%) | catalogued as COSV100470360; called by muse, mutect2
- NPAS3 | c.573C>G p.G191= (on ENST00000356141 / NM_001164749.2; = p.G159= on NM_022123.3) | Silent (SNP) | VAF 42/237 reads (18%) | catalogued as COSV100389331; called by muse, mutect2, varscan2
- RBMS2 | c.768T>C p.A256= | Silent (SNP) | VAF 59/345 reads (17%) | catalogued as COSV100008641; called by muse, mutect2, varscan2
- RPGR | c.1395C>A p.L465= | Silent (SNP) | VAF 11/136 reads (8%) | catalogued as COSV100140323; called by muse, mutect2
- S100PBP | c.723C>A p.I241= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV100758383; called by muse, mutect2, varscan2
- SUN5 | c.969G>A p.Q323= | Silent (SNP) | VAF 17/193 reads (9%) | catalogued as COSV100644889; called by muse, mutect2, varscan2
- TAF6 | c.1272G>A p.Q424= | Silent (SNP) | VAF 21/213 reads (10%) | catalogued as rs145206628, COSV100612837, COSV59840541; called by muse, mutect2, varscan2
- TAF6 | c.165G>A p.L55= | Silent (SNP) | VAF 20/142 reads (14%) | catalogued as rs749987027, COSV100693534; called by muse, mutect2, varscan2
- TENM2 | c.6144C>T p.V2048= (on ENST00000518659 / NM_001122679.2; = p.V1809= on NM_001080428.3) | Silent (SNP) | VAF 19/182 reads (10%) | catalogued as COSV101319357; called by muse, mutect2
- TEX13A | c.279G>T p.L93= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV100781803; called by muse, mutect2, varscan2
- UGGT1 | c.339C>G p.L113= | Silent (SNP) | VAF 27/226 reads (12%) | catalogued as COSV99391042; called by muse, mutect2, varscan2
- VPS39 | c.1734G>A p.P578= (on ENST00000348544 / NM_001301138.2; = p.P567= on NM_015289.5) | Silent (SNP) | VAF 14/172 reads (8%) | catalogued as rs748127127, COSV100529043; called by muse, mutect2
- WDR62 | c.984C>T p.L328= | Silent (SNP) | VAF 13/125 reads (10%) | catalogued as rs200298843, COSV54336596; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WNT6 | c.540C>T p.D180= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV52109627; called by muse, mutect2
- AP000769.3 | chr11:65505803 C>G | 5'Flank (SNP) | VAF 44/152 reads (29%) | called by muse, mutect2, varscan2
- TAF6 | c.-2G>A | 5'UTR (SNP) | VAF 19/176 reads (11%) | catalogued as COSV100693537; called by muse, varscan2
